Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5585, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5585-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

REVISED REPORT (Revised information underlined)

TISSUE DESCRIPTION:

13.5 cm segment right ureter and right kidney (400 grams, 13.5 x 8.3 x 7.5 cm) and lymph nodes from intra-aortocaval and retrocaval regions.

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forms a 9.3 x 7.5 x 6.5 cm mass located in the mid portion of the kidney. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 0.8 cm in greatest linear extent. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor. Multiple (7) renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, intra-aortocaval and retrocaval, excision: Multiple (7) intra-aortocaval and (3) retrocaval lymph nodes are negative for tumor.

AMENDMENTS:

Revision Description:

Grade misinterpreted on frozen section. Should be grade 2 (of 4).
....Original Diagnosis....

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forms a 9.3 x 7.5 x 6.5 cm mass located in the mid portion of the kidney. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 0.8 cm in greatest linear extent. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor. Multiple (7) renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, intra-aortocaval and retrocaval, excision: Multiple (7) intra-aortocaval and (3) retrocaval lymph nodes are negative for tumor.

[page 2 of 2]
[REDACTED]

Surgical Pathology

REVISED REPORT (Revised information underlined)

TISSUE DESCRIPTION:

13.5 cm segment right ureter and right kidney (400 grams, 13.5 x 8.5 x 7.5 cm) and lymph nodes from intra-aortocaval and retrocaval regions.

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forms a 9.3 x 7.5 x 6.5 cm mass located in the mid portion of the kidney. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 0.8 cm in greatest linear extent. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor. Multiple (7) renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, intra-aortocaval and retrocaval, excision: Multiple (7) intra-aortocaval and (3) retrocaval lymph nodes are negative for tumor.

AMENDMENTS:

Revision Description:

Grade misinterpreted on frozen section. Should be grade 2 (of 4).

....Original Diagnosis....

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forms a 9.3 x 7.5 x 6.5 cm mass located in the mid portion of the kidney. The tumor is confined to the kidney. A tumor thrombus is present in the renal vein, 0.8 cm in greatest linear extent. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative for tumor. Multiple (7) renal hilar lymph nodes are identified. The adrenal gland is absent.

Lymph nodes, intra-aortocaval and retrocaval, excision: Multiple (7) intra-aortocaval and (3) retrocaval lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file bbd5b7cb-9463-47dc-8b2e-18f4dde96604 (TCGA-CW-5585.454C3DF5-9E2C-41FD-8315-7EFEE290173F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).